Surgical pathology report (de-identified scan), TCGA case TCGA-D7-5578, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-5578-01A (Primary Tumor).

Examination: **Histopathological examination**

Examination No.: G-

Material: **Total organ resection – stomach**

TCGA – D7 – 5578

Material collected on: Material received on:

Clinical diagnosis: **Bleeding gastric cancer.**

Examination performed on:

Macroscopic description:

Sent material consisting of a part of the stomach, cut out along the greater curvature, sized 17 x 10 cm with the omentum sized 37 x 30 cm, no focal lesions found macroscopically. Tumour sized 7 x 6 x 0.5 cm found on the lesser curvature. Distance from the proximal end 2.7 cm, from distal end, 1,6 cm.

Microscopic description:

Adenocarcinoma tubulare partim male differentiatum G3.

Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae periventricularis. Invasio carcinomatosa vassorum. Surgical incision lines off cancer invaded area. Mucosa free of cancer, showing features of chronic high intensity inflammation with focal intestinal metaplasia.

Omentum sine metastasibus.

Metastases carcinomatosae in lymphonodis No VI / XIX.

Infiltratio carcinomatosae capsulae lymphonodis et telae adiposae perinodalis.

Histopathological diagnosis:

Adenocarcinoma tubulare partim differentiatum ventriculi.

Source: NCI Genomic Data Commons file 720b4252-debe-4e4e-85ea-e827aa5b6ef3 (TCGA-D7-5578.F3951295-E613-4109-84E3-1238C29CF5CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).